Somatic mutation profile of tumor specimen TCGA-F7-8489-01A (aliquot TCGA-F7-8489-01A-31D-2394-08) from TCGA case TCGA-F7-8489, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 48.9 years (17,873 days).
Specimen TCGA-F7-8489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95b388e4-dc64-4c51-911b-042eddac548f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-8489-10A (Blood Derived Normal), aliquot TCGA-F7-8489-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/738a8873-0959-4b75-8cfb-573b8716061e

The open-access MAF lists 153 somatic variants for this specimen: 108 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 41, Nonsense Mutation 9, Intron 3, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3736G>C p.A1246P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100383418, COSV60630364; called by muse, mutect2
- ACE | c.3143A>T p.D1048V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV99327643; called by muse, mutect2
- ACTRT1 | c.816C>G p.S272R | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV100947735; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3373C>A p.R1125S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV101002033, COSV65892039; called by muse, varscan2
- ADCYAP1R1 | c.1245G>C p.W415C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100416900; called by muse, mutect2, varscan2
- ADH7 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99265432; called by muse, mutect2
- AL592490.1 | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV101308268; called by muse, mutect2, varscan2
- ALCAM | c.1725A>C p.E575D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100065548; called by muse, mutect2, varscan2
- ALDH16A1 | c.1508A>T p.Y503F | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.815); catalogued as COSV53196616, COSV99513179; called by muse, mutect2, varscan2
- API5 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101124573; called by muse, mutect2, varscan2
- AQP4 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV101270558; called by muse, mutect2, varscan2
- ARHGAP28 | c.641A>G p.D214G (on ENST00000383472 / NM_001366230.1; = p.D55G on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99151338; called by muse, mutect2
- ATP13A5 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV100665563; called by muse, mutect2
- BAZ1B | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV100290063; called by muse, mutect2, varscan2
- BTN3A1 | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50025054; called by muse, mutect2
- C4BPA | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100891277; called by muse, varscan2
- C6orf62 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100965883; called by muse, mutect2, varscan2
- CC2D1A | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1568416070, COSV100528677; called by muse, mutect2
- CENPJ | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs1414892924, COSV101121570; called by muse, mutect2
- CHD7 | c.2276A>T p.Y759F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101418399; called by muse, mutect2, varscan2
- CSMD1 | c.5457C>A p.Y1819* (on ENST00000520002; = p.Y1818* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100153006; called by muse, mutect2
- CTTNBP2NL | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99600247; called by muse, mutect2, varscan2
- CXCL12 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 8/225 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100639035; called by muse, mutect2
- DNAH2 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); catalogued as COSV50013520; called by muse, mutect2, varscan2
- DNHD1 | c.14103C>A p.D4701E | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99600873; called by muse, mutect2, varscan2
- DOCK7 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV52001441; called by muse, mutect2
- DYRK1A | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV100118232, COSV58292124; called by muse, mutect2, varscan2
- DZIP3 | c.2086C>T p.H696Y | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV64311151; called by muse, mutect2, varscan2
- EFNB3 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs746889388, COSV99872943; called by muse, mutect2, varscan2
- ELMO1 | c.1445A>G p.Q482R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV100165764, COSV60329858; called by muse, mutect2
- ENPEP | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99488053; called by muse, mutect2
- ERICH6 | c.469C>A p.H157N | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs763115627, COSV99901812, COSV99901939; called by muse, mutect2, varscan2
- ETV5 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167819091, COSV100112558; called by muse, mutect2, varscan2
- EZH2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100236588; called by muse, mutect2
- FCGBP | c.4600C>T p.Q1534* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99663813; called by muse, mutect2, varscan2
- FYB2 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 8/133 reads (6%) | catalogued as COSV100599751; called by muse, mutect2
- GABRG1 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54953550, COSV99778624; called by muse, mutect2, varscan2
- GARRE1 | c.208A>C p.T70P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.246); catalogued as COSV100209693; called by muse, mutect2, varscan2
- GCFC2 | c.2318A>G p.H773R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58083421; called by muse, mutect2, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2, varscan2
- GPRASP2 | c.1955C>A p.S652Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176921; called by muse, mutect2
- GRXCR1 | c.571C>G p.R191G | Missense Mutation (SNP) | VAF 47/476 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV101295744, COSV67671089, COSV67674884; called by muse, mutect2, varscan2
- IGF1R | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs1253103806, CM109961, COSV99160977; ClinVar: protective; called by muse, mutect2, varscan2
- IGSF3 | c.3160C>T p.R1054C (on ENST00000369486 / NM_001007237.3; = p.R1074C on NM_001542.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs575047260, COSV100605051; called by muse, mutect2, varscan2
- KATNB1 | c.519C>G p.L173= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101109973; called by muse, mutect2, varscan2
- KCTD19 | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100431180; called by muse, mutect2
- KMT5B | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100430421; called by muse, mutect2, varscan2
- LRRC7 | c.3385C>T p.P1129S (on ENST00000651989 / NM_001370785.2; = p.P1096S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV99229344; called by muse, mutect2
- LRTM2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs757724878, COSV99766228, COSV99766388; called by muse, mutect2, varscan2
- MAST4 | c.3866G>A p.R1289K (on ENST00000403625 / NM_001164664.2; = p.R1100K on NM_015183.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1327934048, COSV99845568; called by muse, mutect2, varscan2
- MOB3B | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99218876; called by muse, mutect2, varscan2
- MUTYH | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100588156; called by muse, mutect2
- MYH2 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99820828; called by muse, mutect2
- OR10Q1 | c.350T>G p.F117C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs944823760, COSV100372377; called by muse, mutect2
- OR5F1 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99558885; called by muse, mutect2
- OR5L1 | c.598T>A p.F200I | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV100450228; called by muse, mutect2, varscan2
- PCDHA12 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1554169356, COSV56501215, COSV56535448; called by muse, mutect2
- PCDHA4 | c.1207A>T p.N403Y | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100793704; called by muse, mutect2, varscan2
- PCDHB3 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.169); catalogued as COSV99166412; called by muse, mutect2, varscan2
- PEX5L | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99829769; called by muse, mutect2
- PEX5L | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99829771; called by muse, mutect2
- PHIP | c.4557G>T p.E1519D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.956); catalogued as COSV99243445, COSV99244808; called by muse, mutect2, varscan2
- PIKFYVE | c.3823G>C p.D1275H | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100011331; called by muse, mutect2
- POLH | c.1473G>C p.Q491H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100947863; called by muse, mutect2, varscan2
- PPL | c.4123A>T p.I1375F | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99278533; called by muse, mutect2
- PSMD1 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs766549158, COSV100433857; called by muse, mutect2, varscan2
- RAD17 | c.242C>T p.S81L (on ENST00000380774 / NM_133339.2; = p.S70L on NM_002873.1) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99281219, COSV99281731; called by muse, mutect2
- RAD52 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1339285918, COSV99942694; called by muse, mutect2, varscan2
- RCC1 | c.75C>T p.V25= | Splice Region (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100868185; called by muse, mutect2, varscan2
- REV3L | c.8254A>G p.I2752V | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.584); catalogued as rs1237343515, COSV100725624; called by muse, mutect2, varscan2
- RGS7 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100470488; called by muse, mutect2, varscan2
- RPLP0 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV99935458; called by muse, mutect2
- RRP7A | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100543792, COSV100543928; called by muse, mutect2, varscan2
- SCN10A | c.3869T>C p.I1290T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101479510; called by muse, mutect2, varscan2
- SFRP2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV56838049; called by muse, mutect2
- SH3RF2 | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV100768000; called by muse, mutect2
- SIPA1L2 | c.4432T>C p.S1478P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV99479483; called by muse, mutect2
- SLC26A7 | c.1970G>C p.*657Sext*15 | Nonstop Mutation (SNP) | VAF 26/255 reads (10%) | catalogued as rs763549753, COSV99404211; called by muse, mutect2, varscan2
- SLC38A2 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as COSV99874074; called by muse, mutect2, varscan2
- SLC4A4 | c.1195T>G p.S399A (on ENST00000264485 / NM_001098484.3; = p.S355A on NM_003759.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99141917; called by mutect2, varscan2
- SMAP1 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100391841; called by muse, varscan2
- SPANXD | c.50A>T p.D17V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100982327; called by mutect2, varscan2
- SPATA25 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV51942926; called by muse, mutect2, varscan2
- ST3GAL1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 20/230 reads (9%) | PolyPhen benign (0.408); catalogued as rs761703135, COSV60614456; called by muse, mutect2
- STX11 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as CM103661, COSV100845522; called by muse, mutect2, varscan2
- SUGP2 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV100432265; called by muse, mutect2
- TAAR9 | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV101453384; called by muse, mutect2
- TGFBR2 | c.830A>T p.K277M | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55455984, COSV99847932; called by muse, mutect2
- TLR4 | c.1297A>C p.N433H (on ENST00000355622 / NM_138554.5; = p.N393H on NM_003266.4) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as COSV100842843; called by muse, mutect2, varscan2
- TNIP1 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762849048, COSV59305344; called by muse, mutect2, varscan2
- TNN | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1412346099, COSV53426041; called by muse, mutect2
- TRIM42 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as rs146006015, COSV53887852; called by muse, mutect2, varscan2
- UNC79 | c.7219G>T p.E2407* (on ENST00000393151 / NM_001346218.2; = p.E2230* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99829637; called by muse, mutect2, varscan2
- WDR59 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100049680; called by muse, mutect2, varscan2
- XRRA1 | c.1601G>C p.S534T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100370064; called by muse, mutect2, varscan2
- YWHAQ | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV99431416; called by muse, mutect2
- YWHAQ | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99431419; called by muse, mutect2
- ZNF33A | c.1078G>C p.E360Q (on ENST00000458705 / NM_006974.3; = p.E361Q on NM_006954.2) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1410404882, COSV100276154; called by muse, mutect2, varscan2
- ZNF567 | c.1846C>T p.P616S (on ENST00000536254 / NM_001322913.1; = p.P585S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100658966; called by muse, mutect2, varscan2
- ZNF600 | c.1433C>G p.A478G | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100593092; called by muse, mutect2
- CD248 | c.1279C>G p.P427A | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- CYB5R2 | c.302dup p.M102Dfs*40 | Frame Shift Ins (INS) | VAF 18/128 reads (14%) | called by mutect2, pindel, varscan2
- GTF3C5 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | called by muse, varscan2
- LRP1 | c.13033del p.S4345Afs*31 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- MSX1 | c.700del p.E234Sfs*5 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- PRKY | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THEG | c.1094dup p.A367Sfs*7 | Frame Shift Ins (INS) | VAF 12/146 reads (8%) | called by mutect2, pindel
- ADGRL4 | c.1725A>T p.I575= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100876492; called by muse, mutect2
- AGFG2 | c.1266C>T p.F422= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs1354881839, COSV53546335; called by muse, mutect2
- APBA2 | c.435G>A p.A145= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs372287836, COSV101382617; called by muse, mutect2, varscan2
- AQP9 | c.594C>T p.L198= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs774154190, COSV99583186; called by muse, mutect2, varscan2
- C12orf54 | c.321A>G p.G107= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV100011677; called by muse, mutect2, varscan2
- CBLN2 | c.561C>T p.G187= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs149543931; called by muse, mutect2, varscan2
- CDHR5 | c.555G>A p.L185= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1449671885, COSV100848630; called by muse, mutect2, varscan2
- CEP97 | c.1383G>A p.E461= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100512051, COSV59123918; called by muse, mutect2, varscan2
- DGKA | c.885G>T p.L295= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV100093363; called by muse, mutect2
- DYNC1H1 | c.13719C>T p.N4573= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs886050377, COSV100795321; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EMX2 | c.758A>G p.*253= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101463632; called by muse, mutect2, varscan2
- FAM168B | c.321G>A p.P107= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as COSV101112236; called by muse, mutect2, varscan2
- FAM172A | c.306A>G p.G102= | Silent (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- GAL3ST3 | c.681C>A p.L227= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100360975; called by muse, mutect2, varscan2
- GRIN3B | c.1779C>T p.T593= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs746618362, COSV52258504; called by muse, mutect2, varscan2
- KCTD19 | c.1815T>C p.P605= | Silent (SNP) | VAF 19/241 reads (8%) | catalogued as COSV100431178; called by muse, mutect2
- LAMA4 | c.693C>T p.D231= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs370231631; called by mutect2, varscan2
- LRP1 | c.2346G>T p.L782= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV99676997; called by muse, mutect2, varscan2
- MAP2K4 | c.1020C>T p.F340= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100796483; called by muse, mutect2, varscan2
- METTL3 | c.219T>A p.A73= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as COSV99398558; called by muse, mutect2, varscan2
- MKI67 | c.3819C>T p.I1273= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as COSV100896928; called by muse, mutect2, varscan2
- NRG3 | c.2022C>T p.Y674= (on ENST00000404547 / NM_001370084.1; = p.Y650= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs376987579; called by muse, mutect2, varscan2
- OR6M1 | c.843C>T p.L281= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1367527978, COSV100484168; called by muse, mutect2, varscan2
- PAK3 | c.207G>A p.E69= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs779707473, COSV99458220; called by muse, mutect2, varscan2
- PCDHB12 | c.1158G>A p.P386= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1409934513, COSV99507736, COSV99507999; called by muse, mutect2, varscan2
- PDHA2 | c.705A>T p.A235= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99757252; called by muse, mutect2
- PLEKHG3 | c.762C>T p.R254= (on ENST00000394691; = p.R310= on NM_001308147.2) | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs752592669, COSV99907036; called by muse, mutect2, varscan2
- PPIL2 | c.348C>T p.I116= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs369102532, COSV58605948; called by muse, mutect2, varscan2
- PRPF18 | c.801T>C p.D267= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100187240; called by muse, mutect2
- RARRES2 | c.234G>A p.R78= | Silent (SNP) | VAF 46/587 reads (8%) | catalogued as COSV99784739; called by muse, mutect2
- SDK2 | c.6477A>C p.P2159= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SUPV3L1 | c.1107C>T p.C369= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV100669864; called by muse, mutect2
- TBC1D9 | c.2619A>G p.G873= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV101464394; called by muse, mutect2
- TELO2 | c.957G>T p.L319= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99248659; called by muse, varscan2
- TOM1L2 | c.438G>A p.R146= (on ENST00000379504 / NM_001350333.2; = p.R96= on NM_001033551.3) | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs1384757622, COSV100541204; called by muse, mutect2, varscan2
- TRIM50 | c.288C>G p.L96= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV52719717; called by muse, mutect2, varscan2
- TXNDC2 | c.1383A>T p.A461= (on ENST00000306084 / NM_001098529.2; = p.A394= on NM_032243.6) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100046547; called by muse, mutect2, varscan2
- UBXN11 | c.1122G>A p.E374= (on ENST00000374221 / NM_183008.2; = p.E341= on NM_145345.2) | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99432898; called by muse, mutect2, varscan2
- ULK1 | c.3108C>T p.C1036= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV100417206; called by muse, mutect2
- VCAN | c.9447C>T p.F3149= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99427086; called by muse, mutect2, varscan2
- ZNF623 | c.304A>C p.R102= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV101513595; called by muse, mutect2
- ARHGAP6 | c.589-35729A>G | Intron (SNP) | VAF 13/70 reads (19%) | catalogued as rs772713297, COSV100499004; called by muse, mutect2, varscan2
- DST | c.4297-4350C>A | Intron (SNP) | VAF 41/182 reads (23%) | catalogued as COSV55007599; called by muse, mutect2, varscan2
- MIR124-2 | n.6G>C | RNA (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- MYBPC1 | c.104-2557G>A | Intron (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100638239; called by muse, mutect2
